Somatic mutation profile of tumor specimen TCGA-ET-A2N0-01A (aliquot TCGA-ET-A2N0-01A-11D-A18F-08) from TCGA case TCGA-ET-A2N0, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 51.2 years (18,692 days).
Specimen TCGA-ET-A2N0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66d209d7-1e4f-4566-9392-70ec174fe0b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A2N0-10A (Blood Derived Normal), aliquot TCGA-ET-A2N0-10A-01D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d48b754-28fd-401e-8572-ffe909fe815f

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 1, RNA 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CACHD1 | c.1591C>G p.P531A | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV51549162; called by muse, mutect2, varscan2
- CHGB | c.1316G>T p.R439M | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs771393741, COSV66759682, COSV66761431; called by muse, mutect2, varscan2
- IGSF9B | c.2678A>G p.D893G | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58064473; called by muse, mutect2, varscan2
- OR51G1 | c.425G>A p.C142Y | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.102); catalogued as COSV58968593; called by muse, mutect2, varscan2
- TACR3 | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as CM103252, COSV59198691; called by muse, mutect2, varscan2
- PIK3R5 | c.872dup p.Y291* | Nonsense Mutation (INS) | VAF 9/27 reads (33%) | called by mutect2, pindel, varscan2
- SLC22A3 | c.1545_1547del p.M515_L516delinsI | In Frame Del (DEL) | VAF 28/95 reads (29%) | called by mutect2, pindel, varscan2
- SLAMF8 | c.105G>T p.L35= | Silent (SNP) | VAF 46/146 reads (32%) | catalogued as COSV56987639; called by muse, mutect2, varscan2
- RNF217-AS1 | n.2811_2812insTA | RNA (INS) | VAF 4/15 reads (27%) | called by mutect2, varscan2
